Surgical pathology report (de-identified scan), TCGA case TCGA-RA-A741, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Candler, specimen TCGA-RA-A741-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT:

ACCT #

LOC:

REG DR:

AGE/SX:

ROOM:

DOB:

BED:

STATUS:

SPEC #:

RECD:

STATUS:

COLL:

TIME IN FORMALIN:

hrs.

COLD ISCHEMIA TIME:

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Cervical CA

Remarks: Send to precision

Specimen(s): A. Cervix and upper vagina

B. Left pelvic lymph node

C. Right pelvic lymph node

ICD-O-3
Carcinoma, squamous cell NOS
Site Cervix NOS
8/11/13
JW 8/11/13

MICROSCOPIC DIAGNOSIS

A. CERVIX AND UPPER VAGINA BIOPSY:

- INVASIVE POORLY DIFFERENTIATED CARCINOMA CONSISTENT WITH SQUAMOUS CELL CARCINOMA, SEE COMMENT

B. LEFT PELVIC LYMPH NODE, DISECTION:

- ONE (1) LYMPH NODE, NEGATIVE FOR METASTASIS (0/1)

C. RIGHT PELVIC LYMPH NODE, DISECTION:

- THREE (3) LYMPH NODES, NEGATIVE FOR METASTASIS (0/3)

COMMENT(S)

A. The biopsy material was received fresh with tissue selected for and tissue banking.

The biopsy shows a dense, cellular proliferation of strands of epithelioid cells with marked, nuclear pleomorphism, hyperchromatic nuclei and varying degrees of eosinophilic cytoplasm. There are also numerous apoptotic cells as well as scattered mitoses. There is an associated lymphohistiocytic infiltrate. Immunohistochemical stains performed include P16, P63, 34BE12, CK5/6 and CEA. P16 shows strong, diffuse nuclear staining. P63 and 34BE12 show diffuse cytoplasmic staining. CK5/6 and CEA stain a minority of cells. These stains are consistent with a squamous cell carcinoma. It is likely of cervical origin. Pankeratin stains performed on the lymph nodes in Parts "B" and "C" are negative for metastasis.

GROSS DESCRIPTION:

A. Received fresh for Tissue Banking is a fragmented, 2.2 x 0.9 x 0.7 cm, indurated, mucinous appearing tissue biopsy. The tissue is bisected and sampled under sterile conditions. Precision Diagnostic, fresh tissue is sampled for Tissue Banking and 50% of the biopsy is submitted for permanent histologic evaluation, cassette 1.

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

SPEC #: [REDACTED]

(Continued)

GROSS DESCRIPTION: (Continued)

Received in two additional parts. Each part is in formalin, labeled with the patient's name.

B. Labeled "left pelvic lymph node" is a 3.4 x 3.3 x 1.2 cm aggregate of yellow, lobulated adipose. The adipose is sectioned to have a single, 1.5 x 1.0 x 0.4 cm nodular fatty lymph node. The node is bisected and entirely submitted cassette B1.

C. Labeled "right pelvic lymph node" is a 3.0 x 2.7 x 1.5 cm aggregate of yellow, lobulated adipose. The adipose is sectioned to have three nodular, fatty lymph nodes. The nodes range from a linear 1.1 x 0.4 x 0.3 cm to an indurated 1.2 x 0.8 x 0.6 cm. The medium sized node is inked blue. Each node is bisected and the nodes are entirely submitted cassettes C1-C2.

Signed ____ (signature on file) ____

** END OF REPORT **

Source: NCI Genomic Data Commons file 0a3ec707-bb3b-4a3b-91a1-8c3de064b86c (TCGA-RA-A741.4CC49B26-FA09-4B3C-BB2F-236914852C7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).